Somatic mutation profile of tumor specimen BA3180D (aliquot aq-BA3180D) from BEATAML1.0 case 2770, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.2 years (9,917 days).
Specimen BA3180D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93bac416-d959-4f39-b062-7abcf1ded308.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3165D (Solid Tissue Normal), aliquot aq-BA3165D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62ec2a2b-cb40-436a-8034-4c5000124d21

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 69/152 reads (45%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.422_423dup p.A142* | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | called by mutect2, varscan2
- DAPK1 | c.999C>T p.S333= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs763422868; called by muse, mutect2, varscan2
